Somatic mutation profile of tumor specimen MMRF_2554_1_BM_CD138pos (aliquot MMRF_2554_1_BM_CD138pos_T1_KHS5U_K15219) from MMRF case MMRF_2554, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.6 years (23,949 days).
Specimen MMRF_2554_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 704ddfa9-3e47-4eb0-87bb-2829a144f2e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2554_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2554_1_PB_Whole_C3_KHS5U_K15218; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c83843e1-8cd7-4ecd-8cca-dd5e0ecf269c

The open-access MAF lists 191 somatic variants for this specimen: 74 protein-altering or splice-affecting, 22 silent, 95 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, 3'UTR 41, Intron 31, Silent 22, 5'UTR 11, RNA 6, Nonsense Mutation 4, 3'Flank 3, 5'Flank 3, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 82/329 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1265899855; called by muse, mutect2
- B3GAT2 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs773823914, COSV57769288; called by muse, mutect2, varscan2
- C14orf39 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs759017367, COSV58785354; called by muse, mutect2, varscan2
- CCDC38 | c.1154T>C p.I385T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.655); catalogued as rs149118920; called by muse, mutect2, varscan2
- CCDC88C | c.4417G>A p.A1473T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs747515656, COSV58662500, COSV58662843; called by muse, mutect2, varscan2
- CNST | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754661102, COSV100830250, COSV63624397; called by muse, mutect2, varscan2
- CPSF4L | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs539774804; called by muse, mutect2, varscan2
- DNAH3 | c.6141C>G p.I2047M | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1415272690; called by muse, mutect2
- ELP1 | c.3851C>T p.T1284I | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1438249652; called by muse, mutect2
- GDPD4 | c.1865A>T p.Y622F | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as COSV60024011; called by muse, mutect2, varscan2
- GMCL2 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs1326384365; called by muse, mutect2
- GRIK5 | c.441G>T p.L147F | Missense Mutation (SNP) | VAF 151/303 reads (50%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.575); catalogued as rs972705356; called by muse, mutect2, varscan2
- GRM3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64472446, COSV64474804; called by muse, mutect2, varscan2
- GTPBP2 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV61077307; called by muse, mutect2, varscan2
- H3C2 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs755336260, COSV52518570; called by muse, mutect2, varscan2
- IGHV2-70 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs544603085; called by muse, varscan2
- IGHV2-70D | c.343T>G p.Y115D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353244740; called by muse, varscan2
- IGHV2-70D | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1414572352; called by muse, varscan2
- IGHV2-70D | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1415610196; called by muse, varscan2
- IGLV3-1 | c.187G>C p.V63L | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs190667156; called by muse, varscan2
- IGLV3-1 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs145774047; called by muse, mutect2, varscan2
- INPP4B | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374251810; called by muse, mutect2, varscan2
- NTN1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99433575; called by muse, mutect2, varscan2
- PCDHA10 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.02); catalogued as rs781975666, COSV56485061; called by muse, mutect2, varscan2
- PCDHAC2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.888); catalogued as rs369053625; called by muse, mutect2, varscan2
- PIAS4 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as rs368259481; called by muse, mutect2, varscan2
- PROM2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs758232721, COSV100468612; called by muse, mutect2, varscan2
- SLC13A4 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs930393636; called by muse, mutect2, varscan2
- SLC4A7 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.991); catalogued as rs1234953013, COSV55405017; called by muse, mutect2, varscan2
- SYT3 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1365912161; called by muse, mutect2, varscan2
- TBX18 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs933484434, COSV100858435; called by muse, mutect2
- TENT5C | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 43/82 reads (52%) | catalogued as rs1426999061; called by muse, mutect2, varscan2
- USH2A | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100229267; called by muse, mutect2
- USP26 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs773981561, COSV63708374; called by muse, mutect2, varscan2
- ZNF521 | c.2667C>A p.D889E | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.684); catalogued as COSV100833219; called by muse, mutect2, varscan2
- ADGRV1 | c.8759T>G p.F2920C | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRM1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- AKAP13 | c.4139A>C p.K1380T | Missense Mutation (SNP) | VAF 166/345 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- CCDC66 | c.730G>C p.A244P (on ENST00000394672 / NM_001353147.1; = p.A210P on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CCDC91 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, mutect2
- CEMIP2 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- COLEC12 | c.1479dup p.G494Rfs*9 | Frame Shift Ins (INS) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- DNAH3 | c.10928T>G p.L3643R | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH3 | c.6262C>G p.L2088V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBN2 | c.4471+2T>C p.X1491_splice | Splice Site (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- FGD5 | c.1217A>G p.E406G | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2
- GDF2 | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- HEATR1 | c.5380A>G p.S1794G | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGHV1-69D | c.173A>T p.Q58L | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, varscan2
- IGHV2-70D | c.234A>T p.K78N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, varscan2
- IGHV2-70D | c.233A>T p.K78I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); called by muse, varscan2
- IGKV2-24 | c.136A>C p.S46R | Missense Mutation (SNP) | VAF 116/120 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, varscan2
- IGLV3-1 | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, varscan2
- KBTBD8 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2
- KDM2A | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MAPK10 | c.37G>A p.V13M (on ENST00000359221 / NM_001351625.2; = p.V51M on NM_002753.5) | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MYEF2 | c.557T>C p.L186S | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYO1E | c.283A>T p.M95L | Missense Mutation (SNP) | VAF 21/365 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- NDOR1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NINL | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- ODF3L2 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHB10 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PCDHGA2 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCLO | c.15326dup p.T5110Dfs*5 | Frame Shift Ins (INS) | VAF 99/270 reads (37%) | called by mutect2, pindel, varscan2
- PRSS35 | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- PRUNE2 | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMC6 | c.688T>A p.W230R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM9B | c.192A>C p.K64N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBB4A | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- XKR5 | c.1699C>A p.H567N | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZNF26 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF578 | c.1751T>G p.I584S | Missense Mutation (SNP) | VAF 170/321 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARPC2 | c.57C>T p.F19= | Silent (SNP) | VAF 61/202 reads (30%) | catalogued as COSV55285957; called by muse, mutect2, varscan2
- CEP170 | c.3540C>T p.T1180= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs777198514; called by mutect2, varscan2
- CFAP52 | c.1707C>T p.V569= | Silent (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- COL6A3 | c.5937G>T p.L1979= | Silent (SNP) | VAF 29/114 reads (25%) | called by muse, mutect2, varscan2
- DEFB110 | c.42C>T p.V14= | Silent (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- EFR3B | c.588C>T p.I196= | Silent (SNP) | VAF 76/133 reads (57%) | catalogued as rs1323938472; called by muse, mutect2, varscan2
- EP300 | c.3948T>G p.P1316= | Silent (SNP) | VAF 57/116 reads (49%) | called by muse, mutect2, varscan2
- FES | c.2010C>T p.G670= | Silent (SNP) | VAF 44/189 reads (23%) | called by muse, mutect2, varscan2
- FOXI2 | c.241C>T p.L81= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- G6PC | c.525T>G p.A175= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- GFI1B | c.992G>A p.*331= | Silent (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- GJA5 | c.132C>T p.S44= | Silent (SNP) | VAF 65/363 reads (18%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.36A>T p.A12= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.333A>G p.T111= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs367992030; called by muse, varscan2
- IL2RB | c.426C>T p.H142= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs1359108955; called by muse, mutect2, varscan2
- JAG2 | c.3369C>T p.S1123= | Silent (SNP) | VAF 28/210 reads (13%) | catalogued as rs138204105; ClinVar: benign; called by muse, mutect2, varscan2
- MAST1 | c.123C>T p.S41= | Silent (SNP) | VAF 88/213 reads (41%) | called by muse, mutect2, varscan2
- OR14C36 | c.672C>T p.L224= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs769618661, COSV58601495, COSV58602585; called by muse, mutect2, varscan2
- POU3F4 | c.852C>T p.S284= | Silent (SNP) | VAF 95/95 reads (100%) | catalogued as COSV100937319; called by muse, mutect2, varscan2
- TENT5C | c.678G>C p.L226= | Silent (SNP) | VAF 41/79 reads (52%) | called by muse, mutect2, varscan2
- TXNDC11 | c.291T>C p.P97= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ABCF2 | c.-42-103A>T | Intron (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- ABI3BP | c.1577-8207T>C | Intron (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- AC007663.1 | n.866G>A | RNA (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- AC053481.2 | n.758G>A | RNA (SNP) | VAF 78/311 reads (25%) | called by muse, mutect2, varscan2
- ACSS1 | c.431+1212dup | Intron (INS) | VAF 79/243 reads (33%) | called by mutect2, pindel, varscan2
- ACTG1 | c.-47G>A | 5'UTR (SNP) | VAF 178/288 reads (62%) | catalogued as rs201009307, COSV59510976; called by muse, mutect2, varscan2
- ACTR2 | c.-62A>G | 5'UTR (SNP) | VAF 44/140 reads (31%) | called by muse, mutect2, varscan2
- ACTR2 | c.-61A>C | 5'UTR (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- ADIRF | c.*72A>T | 3'UTR (SNP) | VAF 82/183 reads (45%) | called by muse, mutect2, varscan2
- AFDN | c.4947+33C>T | Intron (SNP) | VAF 61/160 reads (38%) | called by muse, mutect2, varscan2
- AP004606.1 | n.34G>C | RNA (SNP) | VAF 35/139 reads (25%) | catalogued as COSV101588006; called by muse, mutect2, varscan2
- ARHGAP36 | c.*108G>C | 3'UTR (SNP) | VAF 22/24 reads (92%) | catalogued as COSV99358033; called by muse, mutect2, varscan2
- ATP8B4 | c.2697+37G>T | Intron (SNP) | VAF 36/71 reads (51%) | catalogued as rs760606964; called by mutect2, varscan2
- C2orf49 | c.*1683G>C | 3'UTR (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- CAB39 | c.-44+11937T>G | Intron (SNP) | VAF 61/173 reads (35%) | called by muse, mutect2, varscan2
- CAMK2A | c.*522C>T | 3'UTR (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- CAPS2 | c.1670-2239T>A | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- CCDC171 | c.*2073G>A | 3'UTR (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- CD84 | chr1:160546620 G>A | 3'Flank (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- CDCP1 | c.-7C>T | 5'UTR (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- CHST3 | c.*3056C>A | 3'UTR (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- COX8C | c.*10G>A | 3'UTR (SNP) | VAF 146/302 reads (48%) | catalogued as rs778986970; called by muse, mutect2
- CRACDL | c.-10-22306G>A | Intron (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2
- CRACDL | c.-10-22429G>C | Intron (SNP) | VAF 60/214 reads (28%) | called by muse, varscan2
- CUL3 | c.*719G>A | 3'UTR (SNP) | VAF 57/96 reads (59%) | catalogued as rs913710776; called by muse, mutect2, varscan2
- CXCL5 | c.*1516T>C | 3'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- CXorf38 | c.*682G>T | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- DOK7 | c.533-55G>A | Intron (SNP) | VAF 5/110 reads (5%) | called by muse, mutect2
- ENO2 | c.*695A>T | 3'UTR (SNP) | VAF 6/145 reads (4%) | called by muse, mutect2
- FAM107B | c.*20C>T | 3'UTR (SNP) | VAF 25/60 reads (42%) | catalogued as rs553992860; called by muse, mutect2, varscan2
- FAM172A | c.*2930T>C | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- FOXP1 | c.*3421T>C | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, varscan2
- GHR | c.*166dup | 3'UTR (INS) | VAF 41/112 reads (37%) | catalogued as rs1365171460; called by mutect2, varscan2
- GIPR | c.925-18C>T | Intron (SNP) | VAF 43/182 reads (24%) | called by muse, mutect2, varscan2
- HLA-DPA1 | c.*12+160C>T | Intron (SNP) | VAF 15/191 reads (8%) | catalogued as rs940238779; called by muse, mutect2
- HNRNPLL | c.-162C>T | 5'UTR (SNP) | VAF 27/147 reads (18%) | catalogued as rs1488189625; called by muse, mutect2, varscan2
- HTR1A | c.*126C>T | 3'UTR (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- IGHD2-2 | chr14:105921258 G>A | 5'Flank (SNP) | VAF 49/49 reads (100%) | called by muse, mutect2, varscan2
- JADE1 | c.*1011G>A | 3'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as rs1129142; called by muse, varscan2
- JDP2 | chr14:75473918 ins T | 3'Flank (INS) | VAF 28/53 reads (53%) | called by mutect2, pindel, varscan2
- LINC01164 | n.957C>T | RNA (SNP) | VAF 18/42 reads (43%) | catalogued as rs954531034; called by muse, mutect2, varscan2
- LINC01600 | n.2438T>A | RNA (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- LONP2 | c.*5062G>A | 3'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- LRRC55 | c.-1G>C | 5'UTR (SNP) | VAF 54/213 reads (25%) | catalogued as rs756474995; called by muse, mutect2, varscan2
- MICAL3 | c.*1632A>C | 3'UTR (SNP) | VAF 92/179 reads (51%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851302 G>A | 5'Flank (SNP) | VAF 60/148 reads (41%) | catalogued as rs533550579; called by muse, mutect2, varscan2
- MMP11 | c.338+86A>G | Intron (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- MPZL1 | c.258+58A>G | Intron (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- MVB12B | c.*534G>A | 3'UTR (SNP) | VAF 48/182 reads (26%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-132G>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- NOL8 | c.*77G>A | 3'UTR (SNP) | VAF 62/182 reads (34%) | catalogued as rs1478450844; called by muse, mutect2, varscan2
- NOSIP | c.259-695T>C | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- NR3C1 | c.*2639G>A | 3'UTR (SNP) | VAF 14/230 reads (6%) | catalogued as rs1218211378; called by muse, mutect2
- OR9G4 | c.*114T>C | 3'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- OXLD1 | c.-16A>T | 5'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- PARGP1 | n.2199G>A | RNA (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- PDGFC | c.*1940A>G | 3'UTR (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- PDIA3 | c.168-2151A>G | Intron (SNP) | VAF 42/169 reads (25%) | catalogued as rs1473406404; called by muse, mutect2, varscan2
- PIP4P1 | c.143-102G>A | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- PLEKHA3 | c.*311C>G | 3'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.-93G>A | 5'UTR (SNP) | VAF 12/35 reads (34%) | catalogued as rs1329442687; called by muse, mutect2, varscan2
- PRKRIP1 | c.*446C>T | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- PTPRB | c.4060+102T>C | Intron (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99717767; called by muse, mutect2
- RAB30 | chr11:82978990 G>A | 3'Flank (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- RGS3 | c.*476C>A | 3'UTR (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- RNF10 | c.2143-989T>A | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- RNF168 | c.-450G>A | 5'UTR (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
- SAP18 | c.*766C>G | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- SEC14L1 | c.-240+41C>T | Intron (SNP) | VAF 59/239 reads (25%) | called by muse, mutect2, varscan2
- SEMA3D | c.861+5108A>C | Intron (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- SGCA | c.983+891G>C | Intron (SNP) | VAF 54/185 reads (29%) | called by muse, mutect2, varscan2
- SHOX | c.*546C>A | 3'UTR (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- SIAE | c.*1740G>A | 3'UTR (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- SIRT5 | c.857+4713del | Intron (DEL) | VAF 25/132 reads (19%) | catalogued as rs1174576595; called by mutect2, pindel, varscan2
- SLC25A2 | c.-88C>T | 5'UTR (SNP) | VAF 51/171 reads (30%) | catalogued as COSV53404765; called by muse, mutect2, varscan2
- SLC28A1 | c.461+725C>A | Intron (SNP) | VAF 12/66 reads (18%) | called by mutect2, varscan2
- SLC37A2 | c.*770G>C | 3'UTR (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.*2660G>A | 3'UTR (SNP) | VAF 27/70 reads (39%) | catalogued as rs1029010293; called by muse, mutect2, varscan2
- STX17 | c.*1537A>G | 3'UTR (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- TBC1D5 | c.1852+167A>T | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34576049 G>A | 5'Flank (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- TMEM213 | c.*316T>A | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- TRA2B | c.37-5093G>A | Intron (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- TRAF5 | c.*435A>G | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- TRIM7 | c.989-55G>A | Intron (SNP) | VAF 56/182 reads (31%) | called by muse, mutect2, varscan2
- TSC22D3 | c.*823_*826del | 3'UTR (DEL) | VAF 14/22 reads (64%) | catalogued as rs757390303; called by pindel, varscan2
- USP6NL | c.*1282G>A | 3'UTR (SNP) | VAF 59/115 reads (51%) | called by muse, mutect2, varscan2
- VIPR2 | c.*1237C>T | 3'UTR (SNP) | VAF 61/139 reads (44%) | catalogued as rs923843645; called by muse, mutect2, varscan2
- VPS11 | c.-1204A>G | 5'UTR (SNP) | VAF 173/246 reads (70%) | catalogued as rs531518408; called by muse, mutect2, varscan2
- VPS8 | c.480+56G>T | Intron (SNP) | VAF 26/145 reads (18%) | catalogued as rs778765598; called by muse, varscan2
- VPS8 | c.480+221G>T | Intron (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- VPS8 | c.481-420G>A | Intron (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- XPOT | c.*2718T>G | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- YTHDC1 | c.*1246G>T | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- ZNF804A | c.*255A>C | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
